Somatic mutation profile of tumor specimen TCGA-XJ-A9DK-01A (aliquot TCGA-XJ-A9DK-01A-11D-A377-08) from TCGA case TCGA-XJ-A9DK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-XJ-A9DK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d77e8bf-7020-4a1e-89be-2de7ec354fed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XJ-A9DK-10A (Blood Derived Normal), aliquot TCGA-XJ-A9DK-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c05d3448-b137-4853-b61b-f94d465fcda9

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRG2 | c.1456C>T p.R486W (on ENST00000361925 / NM_001375343.1; = p.R446W on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs796052515, COSV62716724, COSV62717465; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- CTSL | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221305842, COSV100446652; called by muse, mutect2
- SYT10 | c.1564A>T p.T522S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); catalogued as COSV99951286; called by muse, mutect2
